Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACT, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACT-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: HCC

Specimen : liver

Gross Photo : 0

GROSS:

Specimen:

Liver: 20.5 x 9.5 x 3.5 cm, 226.5 gm (unfixed)

Operation: Left lateral segmentectomy

Lesion: A well-defined, oval, lobulated mass

Size: 6.0 x 4.0 x 4.0 cm

Cut surface: Yellowish tan with bile-pigmented (necrosis: no)

Gross type: Expanding nodular

Resection margin: Not involved grossly (safety margin: 0.6 cm)

Others:

Satellite nodule: No

Remaining parenchyma: Unremarkable

Portal vein invasion: No

Gross photo: Present

Blocks

T1-4, tumor and surrounding tissue x 4

L, remaining parenchyma of liver x 1

RM, resection margin of liver x 1

MICROSCOPIC:

Hepatocellular carcinoma: Yes

The worst differentiation II

The major differentiation II

Histologic type: Trabecular

Cell type: Hepatic (95%) and clear (5%)

Fatty change: No

Fibrous capsule formation: No

Capsular infiltration: No

Septum formation: Yes

Surgical resection margin invasion: No

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: No

Intrahepatic metastasis: No

Multicentric occurrence: No

Non-tumor liver pathology

1. Chronic hepatitis: Yes

ICD-O-3

Carcinoma, hepatocellular NOS

8170/3

Site Liver C22.0

5/19/14

[page 2 of 2]
Reason (circle)	Not Reviewed	Not Reviewed

Source: NCI Genomic Data Commons file d1dd0217-51c5-4d33-b9bb-bccca9717386 (TCGA-DD-AACT.0A9193A6-4600-44F8-88AD-264F8F2D7B4E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).